Gene-level copy-number profile of tumor specimen TCGA-IB-A7M4-01A from TCGA case TCGA-IB-A7M4, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Body of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 81.6 years (29,792 days).
Specimen TCGA-IB-A7M4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PAAD.e57bab2b-d666-45bb-9b8b-fc2e4d6757b1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-IB-A7M4-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6b9eea16-94bc-40f4-8bfc-f2c6dc6dd926

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 45; copy number 2: 9,729; copy number 3: 12,472; copy number 4: 30,969; copy number 5: 4,132; copy number 6: 186; copy number 7: 1,641; copy number 8: 81; copy number 9: 496; copy number 11: 13; copy number 14: 49.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-IB-A7M4-01A-11D-A36N-01): tumor purity 0.48, ploidy 1.98, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 558 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:36,764,445–38,704,855, 61 genes, copy number 9–14 (broad region; genes not listed).
- chr8:122,414,332–145,066,685, 441 genes, copy number 9 (broad region; genes not listed).
- chr18:22,088,060–22,647,688, 13 genes, copy number 11: AC091043.1, RNU6ATAC20P, GATA6-AS1, GATA6, AC091588.1, RNU6-702P, AC091588.3, AC091588.2, AC027449.1, CTAGE1, ATP7BP1, RPS4XP18, RNU6-1032P.
- chr18:30,954,820–32,131,561, 39 genes, copy number 9: AC016382.1, RNU6-857P, DSC3, DSC2, DSCAS, DSC1, AC012417.1, DSG1, DSG1-AS1, RNU6-167P, DSG4, Y_RNA, DSG3, AC021549.1, DSG2, DSG2-AS1, TTR, B4GALT6, AC017100.1, RN7SKP44, LRRC37A7P, AC017100.2, SLC25A52, TRAPPC8, AC022960.1, AC022960.3, AC022960.2, RNU6-1050P, AC009831.1, PGDP1, AC009831.2, AC009831.4, RNF125, AC011825.3, AC009831.3, AC011825.1, AC011825.4, RNF138, AC011825.2.
- chr18:32,176,050–32,249,032, 4 genes, copy number 9: RNA5SP453, MEP1B, CLUHP6, AC015563.1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
